Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABXP, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABXP-TTP1-A (Primary Tumor).

[page 1 of 8]
**Surgical Pathology Report
Addendum Present**

*** Converted Case * This report may not match the original report format**

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB/Age: [REDACTED] Sex: F
Facility: [REDACTED]
Location: [REDACTED]
Patient Type: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Status: [REDACTED]
Obtained: +15
Received: +18
Reported: +28

FINAL PATHOLOGIC DIAGNOSIS

DESIGNATED BIFRONTAL BRAIN TUMOR, EXCISION BIOPSY:
- ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III)

Comment

Tissue has been submitted for chromosome deletion studies (1p/19q) at [REDACTED]. An addendum and a separate report will be issued once the results are available.

[REDACTED] reviewed this case and concur.

[REDACTED] was notified of the preliminary diagnosis on [REDACTED] and the final diagnosis on [REDACTED] per voice mail. +19 +26

Addendum

Status: Signed Out

Immunohistochemistry for p53 is negative (positive external control).

Addendum

Status: Signed Out

Per report from [REDACTED] the tumor shows deletion of 1p36 in 38% of the cells and deletion of 19q13 in 38% of the cells. In addition, polysomy was detected in 68-75% of the cells.

Microscopic Description

Sections show a tumor composed of areas with cells showing small, round, relatively uniform nuclei with occasional perinuclear

[page 2 of 8]
halos and areas with numerous cells showing brightly eosinophilic cytoplasm and eccentric nuclei that are slightly angulated. There are rare mitotic figures and focal probable vascular endothelial proliferation is noted. No necrosis is identified. Immunohistochemical studies show the astrocytic appearing foci to be WT-1 strongly positive and GFAP positive (positive internal and external controls). Ki-67 is focally increased to 7-9% (positive external control). Immunohistochemistry for p53 is pending and an addendum will be issued with the findings.

Clinical History

Bifrontal craniotomy for tumor.

Brain tumor.

Gross Description

Submitted fresh, designated bifrontal brain tumor, are three fragments of glistening gray tissue. Each of these measures approximately 0.3cm in maximum dimension. A cytology squash preparation is made and all remaining tissue is submitted for frozen examination. **CYTOLOGY AND FROZEN SECTION DIAGNOSIS: Mixed oligoastrocytic glioma, favor grade II-III; final diagnosis deferred to permanent section.** The frozen section control is submitted in block A.

Submitted fresh, designated additional brain tumor, are two fragments of tan/red soft tissue. Each of these measures approximately 0.4cm in maximum dimension. These are totally submitted for frozen examination. **FROZEN SECTION DIAGNOSIS: Mixed oligoastrocytic glioma, probable grade III; final diagnosis deferred to permanent section.** The frozen section control is submitted in block B.

Submitted fresh, designated additional brain tumor, is a single fragment of tan/red soft tissue, measuring 0.6cm in maximum dimension. This specimen is totally submitted for permanent section in cassette C.

The specimen is received in formalin and is designated brain tumor. It consists of multiple fragments of tan tissue, measuring in aggregate 5.0 x 5.0 x 0.3cm. The entire specimen is submitted into cassettes D-H.

Grossed by:

Specimen(s) Received

A: CONVERTED PART - BRAIN TUMOR

Other Related Clinical Data

Physician(s):
Facility:
Service:
Billing Type:

[page 3 of 8]
Transcription Result

Type	ID	Date and Time	Author
Procedures	[REDACTED]	[REDACTED]	[REDACTED]
		+334	

Procedure Orders:

1. MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST [REDACTED]

+334

Document Text

MRI BRAIN W/ CONTRAST

** HISTORY **:

Brain tumor (glioblastoma multiforme) on chemotherapy. Follow-up.

** FINDINGS **:

Technique: Sagittal T1, axial FSE T2, FLAIR, DWI, T1, post gadolinium axial and coronal T1 sequences.

Comparison: [REDACTED], [REDACTED] and [REDACTED] MRI's.

+280

+202

+28

Compared with prior films, there are findings compatible with mild interval progression. This is most evident along the along the upper medial left frontal lobe. Best appreciated on image is 19 and 20 of series 7 (post gadolinium axial T1) and image 16 of series 8) post gadolinium coronal T1) the enhancing solid and cystic mass is mildly larger in this area. For reference measurements, this specific area measures 3.4 x 3.5 x 2.1 cm (previously 3.3 x 2.7 x 2.0 cm). Compared with [REDACTED], there is significant interval enlargement.

+202

In addition, there is also increased white matter T2 hyperintensity within the left frontal lobe compatible with vasogenic edema or nonenhancing tumor infiltration.

The remaining mass and minimal right-sided white matter T2 signal changes has not significantly changed since [REDACTED] Minimal leptomenigeal and dural enhancement along the left frontal lobe is unchanged.

+202

Since [REDACTED] there is is now complete effacement of the left frontal horn.

Expected intracranial flow voids of the major vessels are present. No evidence for acute infarction. The exam is otherwise unchanged.

** IMPRESSION **:

Increased masslike enhancement along the upper medial left frontal lobe portion of patient's clinically known glioblastoma multiforme. There is also increased white matter T2 hyperintensity within the left frontal lobe compatible with vasogenic edema or nonenhancing tumor infiltration. Findings are compatible with mild tumor progression. The remaining mass and minimal right-sided T2 signal changes have not significantly changed.

+334

Results discussed with [REDACTED] voice mail at [REDACTED]

[page 4 of 8]
(MR #) **+334**

DD: [REDACTED] DT: [REDACTED]

[page 5 of 8]
Transcription Result

Type	ID	Date and Time	Author
Procedures	[REDACTED]	[REDACTED] +392	[REDACTED]

Procedure Orders:

1. MRI BRAIN [REDACTED] ordered by [REDACTED]

Document Text

MRI OF THE BRAIN

** HISTORY **:

Brain tumor on therapy. Follow-up.

** FINDINGS **:

MRI of the brain was performed. Sequences include T1 sagittal, T2 axial, axial flair, diffusion axial, T1 axial and post gadolinium T1 axial and coronal images through the brain.

+334

Comparison is made to a brain MRI from [REDACTED]. Again seen are the changes of left frontal craniotomy. Since the previous examination, the heterogeneously enhancing mass involving the frontal lobes, left greater than right, has decreased in size. The mass now measures approximately 4.3 x 1.9 x 5.0 cm in dimension (previously it measured 5.2 x 3.3 x 5.6 cm). There is less T2 signal abnormalities surrounding the mass. There is less effacement of the frontal horns of the lateral ventricles and less effacement of the third ventricle.

There is no new T2 signal abnormality. There are no new areas of enhancement. Flow voids identified within the major vessels of the circle of Willis. The dural venous sinuses are patent.

The orbits and extracranial soft tissues are normal. The visualized paranasal sinuses and mastoid air cells are clear.

** IMPRESSION **:

Since the previous examination, there has been interval decreased size of the heterogeneously enhancing mass involving the frontal lobes, left greater than right. There also is less T2 signal abnormality surrounding the mass and less mass effect on the lateral and third ventricles.

[REDACTED]

DD: [REDACTED] DT: [REDACTED]

+334

+334

[REDACTED]

[page 6 of 8]
Transcription Result

Type	ID	Date	Author
Procedures	[REDACTED]	[REDACTED] +3316	[REDACTED]

Procedure Orders:

1. MRI BRAIN WO AND W CONTRAST [REDACTED] ordered by [REDACTED]

Document Text

MRI BRAIN WITHOUT AND WITH CONTRAST [REDACTED]

** HISTORY **:

Followup anaplastic astrocytoma. [REDACTED]

Comparison:

+3218

+2947

+1819

** FINDINGS **:

Technique: Sagittal T1, axial T2, axial FLAIR, coronal MPGR, axial T1 and axial DWI sequences. Post contrast axial and coronal T1 sequences.

The examination is partially degraded secondary to patient motion.

Status post left frontal craniotomy with underlying cystic encephalomalacia extending to the genu of the corpus callosum with ex-vacuo dilatation of the left frontal horn. Confluent T2 hyperintensity within the bifrontal white matter with extension across the corpus callosum and anterior left external capsule is stable. Nonenhancing infiltrative T2 hyperintensity centered in the inferior left frontal lobe extending to the anterior margin of the third ventricle and abutting the left A1 segment is grossly unchanged. Postcontrast images demonstrate stable linear enhancement beneath the craniotomy site compatible with postoperative changes. No new enhancing lesions.

No reduced diffusion or acute ischemia. Ventricles are stable. No evidence of acute hydrocephalus.

Orbits and paranasal sinuses are grossly unremarkable. The major intracranial flow voids are grossly patent.

** IMPRESSION **:

Status post left frontal craniotomy with stable postoperative changes and cystic encephalomalacia. Bifrontal confluent white matter T2 hyperintensity is unchanged and compatible with post treatment changes. Additional infiltrative T2 hyperintensity centered in the inferior left frontal lobe with extension slightly across the midline anterior to the third ventricle is stable and suspicious for nonenhancing tumor. No evidence of tumor progression.

[page 7 of 8]
(MR #)

DD:

DT:

[REDACTED]

+3316

[REDACTED]

[REDACTED]

[page 8 of 8]
Surgical Pathology Report Addendum Present

* Converted Case * This report may not match the original report format

Patient Name:
Med. Rec. #:
DOB/Age: (Age: , Sex: F
Facility:
Location:
Patient Type:
Physician(s):

Accession #:
Status:
Obtained:
Received:
Reported:

FINAL PATHOLOGIC DIAGNOSIS

DESIGNATED BIFRONTAL BRAIN TUMOR, EXCISION BIOPSY:
- ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III)

Comment

Tissue has been submitted for chromosome deletion studies (1p/19q) at . An addendum and a separate report will be issued once the results are available.

and reviewed this case and concur.

was notified of the preliminary diagnosis on and the final diagnosis on per voice mail.

*** Report Released by

ICD - 0 - 3
oligoastrocytoma, anaplastic 9382/3
Site: brain, frontal C 71.1

ICD - 10
C 71.1

hw
9/9/15

Addendum

Status: Signed Out

Immunohistochemistry for p53 is negative (positive external control).

*** Report Released by

Addendum

Status: Signed Out

Per report from the tumor shows deletion of 1p36 in 38% of the cells and deletion of 19q13 in 38% of the cells. In addition, polysomy was detected in 68-75% of the cells.

*** Report Released by ***

Microscopic Description

Sections show a tumor composed of areas with cells showing small, round, relatively uniform nuclei with occasional perinuclear

Source: NCI Genomic Data Commons file a3ea1116-c9b7-4e70-a58e-2bebb16b6f82 (ER0151 ER-ABXP Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).